Gene-level copy-number profile of tumor specimen MP2PRT-PAUUWK-TMP1-A from MP2PRT case MP2PRT-PAUUWK, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.7 years (1,365 days).
Specimen MP2PRT-PAUUWK-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 3f120deb-d692-495a-8e08-844756d80776.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PAUUWK-NB1-A (blood derived cancer - peripheral blood, post-treatment); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,236 have no estimate.
https://portal.gdc.cancer.gov/files/1eb7484a-8fd8-432f-8de1-081d557e8d48

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 174; copy number 1: 531; copy number 2: 57,677; copy number 3: 5.

Homozygous deletions (total copy number 0; autosomes only): 174 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:89,078,010–89,078,784, 1 gene (within-gene range 0–2): IGKV2-14.
- chr7:38,257,879–38,311,808, 7 genes (within-gene range 0–2): TRGC1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1.
- chr14:22,438,547–22,450,139, 4 genes (within-gene range 0–2): TRDD1, TRDD2, TRDD3, TRDJ1.
- chr14:105,672,308–106,631,653, 150 genes (within-gene range 0–2) (broad region; genes not listed).
- chr14:106,637,718–106,639,657, 2 genes (within-gene range 0–1): IGHVII-60-1, IGHV4-61.
- chr14:106,657,725–106,672,073, 3 genes (within-gene range 0–1): IGHV3-64, IGHV3-65, IGHVII-65-1.
- chr14:106,680,603–106,704,286, 7 genes: IGHV1-67, SLC20A1P1, IGHVII-67-1, IGHVIII-67-2, IGHVIII-67-3, IGHVIII-67-4, IGHV1-68.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 531. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
